Somatic mutation profile of tumor specimen TCGA-ZG-A8QW-01A (aliquot TCGA-ZG-A8QW-01A-11D-A377-08) from TCGA case TCGA-ZG-A8QW, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.9 years (26,632 days).
Specimen TCGA-ZG-A8QW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f57da937-156f-40fd-8f08-371e2b9bdf0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A8QW-10A (Blood Derived Normal), aliquot TCGA-ZG-A8QW-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ec4caa2-988b-4a84-b6ab-7fd2b24446d2

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 19, Silent 11, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F11 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs145564844; called by muse, mutect2
- EP300 | c.6950G>A p.R2317Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs149456776, COSV54330438; ClinVar: not provided; called by muse, mutect2, varscan2
- EXOC4 | c.60dup p.S21Lfs*14 | Frame Shift Ins (INS) | VAF 13/70 reads (19%) | catalogued as rs1430141106; called by mutect2, pindel, varscan2
- GLYR1 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs779659960, COSV100424328; called by muse, mutect2, varscan2
- HSPA14 | c.1136T>C p.I379T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1278463418, COSV101000677; called by muse, mutect2
- NDST2 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100014068; called by muse, mutect2, varscan2
- NPAP1 | c.2872C>A p.P958T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1460433136, COSV100275553; called by muse, mutect2, varscan2
- NSG1 | c.553G>C p.A185P | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1256024403, COSV100086220; called by muse, mutect2
- P2RX1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs367615874, COSV99844894; called by muse, mutect2, varscan2
- PAX5 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100814326; called by muse, varscan2
- PDLIM5 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.11); catalogued as COSV100523835; called by mutect2, varscan2
- POGLUT2 | c.573C>G p.H191Q | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101050801; called by muse, mutect2, varscan2
- PRMT3 | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100423973; called by muse, mutect2, varscan2
- RASL12 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs148588039, COSV54981888; called by muse, mutect2, varscan2
- RFXAP | c.708+2T>C p.X236_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99715183; called by muse, mutect2, varscan2
- RPRD2 | c.889A>T p.N297Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100955121; called by muse, varscan2
- SLC6A15 | c.856T>C p.F286L | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as COSV57024649; called by muse, mutect2
- TPSAB1 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1334657670, COSV58782724; called by muse, mutect2, varscan2
- UNC79 | c.2994A>T p.Q998H (on ENST00000393151 / NM_001346218.2; = p.Q821H on NM_020818.5) | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.409); catalogued as COSV99828305; called by muse, mutect2, varscan2
- ZNF839 | c.814G>A p.V272M (on ENST00000558850 / NM_001267827.1; = p.V388M on NM_018335.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.227); catalogued as COSV99216289; called by muse, mutect2, varscan2
- DBI | c.252dup p.Y85Ifs*19 (on ENST00000355857 / NM_001079862.3; = p.Y102Ifs*19 on NM_020548.8 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- UBR4 | c.4322G>T p.S1441I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.249); called by muse, mutect2
- AFG3L2 | c.240A>G p.G80= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99301952; called by muse, mutect2
- ASH1L | c.6249T>A p.V2083= (on ENST00000368346 / NM_001366177.2; = p.V2078= on NM_018489.3) | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV100853473; called by muse, mutect2, varscan2
- HSPH1 | c.447A>C p.T149= | Silent (SNP) | VAF 55/246 reads (22%) | catalogued as COSV100184992; called by muse, mutect2, varscan2
- KCNA7 | c.1302C>T p.D434= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs145070146; called by muse, mutect2, varscan2
- KCNJ8 | c.807C>T p.H269= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs745683723, COSV53718320; ClinVar: likely benign; called by muse, mutect2, varscan2
- MIA3 | c.5514A>T p.G1838= | Silent (SNP) | VAF 20/360 reads (6%) | catalogued as COSV100388341; called by muse, mutect2
- NDUFB5 | c.546T>A p.S182= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV99372576; called by muse, mutect2
- PRKD2 | c.114C>T p.I38= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99354372; called by muse, mutect2, varscan2
- RNF183 | c.162G>A p.L54= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- ZNF521 | c.636G>A p.L212= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100832483; called by muse, mutect2, varscan2
- ZNF83 | c.154T>C p.L52= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV99991423; called by muse, mutect2, varscan2
